CCDI case PBCKPA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c233344d-749e-4b8c-bec8-0dee57a4fccb

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.1 years (5,879 days).

Biospecimens (3 samples)
- Sample 0DU3KO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU3KS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DU3MT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
